Somatic mutation profile of tumor specimen TCGA-L7-A56G-01A (aliquot TCGA-L7-A56G-01A-21D-A27G-09) from TCGA case TCGA-L7-A56G, project TCGA-ESCA (Esophageal Carcinoma). Sex at birth: male; Vital status: Dead; Primary diagnosis: Squamous cell carcinoma, NOS; Tissue or organ of origin: Lower third of esophagus; Tumor grade: G3; Age at diagnosis: 66.0 years (24,106 days).
Specimen TCGA-L7-A56G-01A: Sample type: Primary Tumor; Tissue type: Tumor; Tumor descriptor: Primary; Specimen type: Solid Tissue.
Source: NCI Genomic Data Commons open-access Masked Somatic Mutation file (Mutation Annotation Format, MAF) 4573b2b3-6e9c-40b9-a709-9199a0af1ffe.wxs.aliquot_ensemble_masked.maf.gz, workflow Aliquot Ensemble Somatic Variant Merging and Masking; Data Release 46.0 - August 10, 2026. Variants were called in the tumor against matched normal specimen TCGA-L7-A56G-10A (Blood Derived Normal), aliquot TCGA-L7-A56G-10A-01D-A27G-09; read counts below are tumor reads.
https://portal.gdc.cancer.gov/files/07127739-6c76-479a-a349-bb2c9ff200b5

The open-access MAF lists 85 somatic variants for this specimen: 62 protein-altering or splice-affecting, 20 silent, 3 other (UTR, intronic, flanking, RNA and similar).
By variant classification: Missense Mutation 52, Silent 20, Nonsense Mutation 4, Frame Shift Del 3, Splice Site 2, RNA 2, Frame Shift Ins 1, Intron 1.

Variants (all; order: hotspot or ClinVar-pathogenic variants first, then other protein-altering variants with a dbSNP/COSMIC/ClinVar record ('catalogued as' / 'ClinVar'), then the remaining protein-altering, then silent, then non-coding — alphabetical by gene within each group; each line: gene | DNA and protein change | classification | tumor variant allele fraction (VAF) | annotations). Protein positions are numbered on GDC's canonical Ensembl transcript (GENCODE v36); where an older RefSeq transcript numbers the protein differently, the line names both transcripts and gives that numbering too:
- ADAMTS18 | c.3550G>T p.E1184* | Nonsense Mutation (SNP) | VAF 10/40 reads (25%) | catalogued as rs752976883; called by muse, mutect2
- AK5 | c.58G>T p.E20* | Nonsense Mutation (SNP) | VAF 18/94 reads (19%) | catalogued as COSV58357098; called by muse, mutect2, varscan2
- CCDC85A | c.911C>T p.T304M | Missense Mutation (SNP) | VAF 5/48 reads (10%) | SIFT tolerated, low confidence (0.13); PolyPhen benign (0.006); catalogued as COSV101339378; called by muse, mutect2
- COL14A1 | c.2606C>T p.P869L | Missense Mutation (SNP) | VAF 8/56 reads (14%) | SIFT tolerated (0.06); PolyPhen benign (0.029); catalogued as COSV52866289; called by muse, varscan2
- CRELD2 | c.643G>A p.G215S | Missense Mutation (SNP) | VAF 11/59 reads (19%) | SIFT tolerated (0.73); PolyPhen benign (0.003); catalogued as rs755543544; called by muse, mutect2, varscan2
- DNAAF5 | c.2510C>T p.S837L | Missense Mutation (SNP) | VAF 11/74 reads (15%) | SIFT deleterious (0); PolyPhen benign (0.306); catalogued as rs115620965; called by muse, mutect2, varscan2
- EBF1 | c.1115G>A p.R372H | Missense Mutation (SNP) | VAF 13/36 reads (36%) | SIFT deleterious (0); PolyPhen possibly damaging (0.884); catalogued as rs200547458; called by muse, mutect2, varscan2
- FAT2 | c.7591A>G p.I2531V | Missense Mutation (SNP) | VAF 29/46 reads (63%) | SIFT tolerated (0.11); PolyPhen benign (0.224); catalogued as COSV55820839; called by muse, mutect2, varscan2
- HOXA10 | c.635G>A p.G212D | Missense Mutation (SNP) | VAF 7/39 reads (18%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as rs886915201, COSV52230095; called by muse, mutect2, varscan2
- NOTCH3 | c.1187C>A p.S396Y | Missense Mutation (SNP) | VAF 48/96 reads (50%) | SIFT deleterious (0); PolyPhen probably damaging (0.979); catalogued as CM125147; called by muse, varscan2
- OGT | c.2599C>T p.R867C | Missense Mutation (SNP) | VAF 28/40 reads (70%) | SIFT deleterious (0); PolyPhen probably damaging (0.969); catalogued as COSV101035519; called by muse, mutect2, varscan2
- PGR | c.98C>T p.A33V | Missense Mutation (SNP) | VAF 17/32 reads (53%) | SIFT tolerated, low confidence (0.05); PolyPhen benign (0.062); catalogued as rs779538755; called by muse, mutect2, varscan2
- PUF60 | c.680G>A p.R227H (on ENST00000526683 / NM_001362896.2; = p.R210H on NM_014281.5 and 2 other RefSeq transcripts) | Missense Mutation (SNP) | VAF 22/97 reads (23%) | SIFT deleterious (0); PolyPhen possibly damaging (0.586); catalogued as rs1361458345; called by muse, mutect2, varscan2
- RBM6 | c.1444A>T p.M482L | Missense Mutation (SNP) | VAF 19/48 reads (40%) | SIFT tolerated (0.52); PolyPhen benign (0); catalogued as COSV56486972; called by muse, mutect2, varscan2
- RUNX1T1 | c.1595C>T p.A532V (on ENST00000265814 / NM_001198628.1; = p.A505V on NM_004349.4 and 1 other RefSeq transcript) | Missense Mutation (SNP) | VAF 6/66 reads (9%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as COSV56153829; called by muse, mutect2
- STXBP5 | c.622G>A p.E208K | Missense Mutation (SNP) | VAF 17/80 reads (21%) | SIFT tolerated (0.1); PolyPhen probably damaging (0.911); catalogued as rs367614502; called by muse, mutect2, varscan2
- SYCP2 | c.46G>A p.D16N | Missense Mutation (SNP) | VAF 23/57 reads (40%) | SIFT tolerated (0.07); PolyPhen benign (0.031); catalogued as COSV100698489; called by muse, mutect2, varscan2
- THBS2 | c.3106C>T p.R1036C | Missense Mutation (SNP) | VAF 14/62 reads (23%) | SIFT deleterious (0); PolyPhen probably damaging (0.992); catalogued as rs138017175; called by muse, mutect2, varscan2
- TMEFF2 | c.852G>A p.M284I | Missense Mutation (SNP) | VAF 27/91 reads (30%) | SIFT tolerated (0.4); PolyPhen benign (0.022); catalogued as COSV55828114; called by muse, mutect2, varscan2
- TRMT112 | c.40C>T p.R14W | Missense Mutation (SNP) | VAF 20/59 reads (34%) | SIFT deleterious (0); PolyPhen benign (0.021); catalogued as rs200904021; called by muse, mutect2, varscan2
- ZNF524 | c.650C>T p.A217V | Missense Mutation (SNP) | VAF 25/77 reads (32%) | SIFT tolerated (0.45); PolyPhen benign (0.036); catalogued as rs1404848070, COSV55608475; called by muse, mutect2, varscan2
- AC127029.3 | c.325C>T p.L109F | Missense Mutation (SNP) | VAF 6/62 reads (10%) | SIFT deleterious (0); PolyPhen benign (0.006); called by muse, mutect2
- AKT1S1 | c.290_299del p.T97Kfs*31 (on ENST00000344175 / NM_001098633.4; = p.T117Kfs*31 on NM_032375.5) | Frame Shift Del (DEL) | VAF 23/60 reads (38%) | called by mutect2, pindel, varscan2
- APBB3 | c.611G>A p.G204E | Missense Mutation (SNP) | VAF 5/33 reads (15%) | SIFT deleterious (0); PolyPhen probably damaging (1); called by muse, mutect2
- BCR | c.1424A>T p.D475V | Missense Mutation (SNP) | VAF 16/38 reads (42%) | SIFT deleterious (0); PolyPhen benign (0.018); called by muse, mutect2, varscan2
- C2CD2L | c.682-1G>A p.X228_splice | Splice Site (SNP) | VAF 8/17 reads (47%) | called by muse, mutect2, varscan2
- CEACAM20 | c.1578G>T p.M526I | Missense Mutation (SNP) | VAF 7/48 reads (15%) | SIFT tolerated (0.08); PolyPhen benign (0.086); called by muse, mutect2, varscan2
- CIAO1 | c.490-1G>T p.X164_splice | Splice Site (SNP) | VAF 19/63 reads (30%) | called by muse, mutect2, varscan2
- DDR1 | c.1453C>T p.Q485* | Nonsense Mutation (SNP) | VAF 26/76 reads (34%) | called by muse, mutect2
- DNA2 | c.2206C>A p.Q736K | Missense Mutation (SNP) | VAF 8/48 reads (17%) | SIFT tolerated (0.29); PolyPhen benign (0.033); called by muse, mutect2, varscan2
- DNAH5 | c.10037C>G p.T3346S | Missense Mutation (SNP) | VAF 3/41 reads (7%) | SIFT tolerated (0.4); PolyPhen benign (0.001); called by muse, mutect2
- DOK1 | c.1249A>T p.T417S | Missense Mutation (SNP) | VAF 6/17 reads (35%) | SIFT tolerated (0.58); PolyPhen benign (0.001); called by muse, mutect2, varscan2
- ELAVL4 | c.197T>G p.F66C | Missense Mutation (SNP) | VAF 6/84 reads (7%) | SIFT deleterious (0); PolyPhen probably damaging (1); called by muse, mutect2
- EPS15 | c.1983A>C p.Q661H | Missense Mutation (SNP) | VAF 22/44 reads (50%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.927); called by muse, varscan2
- FBXO10 | c.2482G>A p.G828R | Missense Mutation (SNP) | VAF 13/42 reads (31%) | SIFT deleterious (0); PolyPhen possibly damaging (0.59); called by muse, mutect2, varscan2
- FIP1L1 | c.259A>T p.S87C | Missense Mutation (SNP) | VAF 19/77 reads (25%) | SIFT deleterious (0); PolyPhen possibly damaging (0.867); called by muse, mutect2, varscan2
- HERC1 | c.4405G>A p.E1469K | Missense Mutation (SNP) | VAF 13/44 reads (30%) | SIFT tolerated (0.28); PolyPhen benign (0.021); called by muse, mutect2, varscan2
- ITGA2 | c.2653A>G p.R885G | Missense Mutation (SNP) | VAF 22/46 reads (48%) | SIFT tolerated (0.37); PolyPhen benign (0.003); called by muse, mutect2, varscan2
- KIAA0930 | c.1166T>G p.I389S (on ENST00000336156 / NM_001009880.2; = p.I394S on NM_015264.2) | Missense Mutation (SNP) | VAF 10/47 reads (21%) | SIFT deleterious (0); PolyPhen benign (0.36); called by muse, mutect2, varscan2
- LDB1 | c.467C>T p.S156F (on ENST00000425280 / NM_001321612.2; = p.S120F on NM_003893.5) | Missense Mutation (SNP) | VAF 25/43 reads (58%) | SIFT tolerated (0.29); PolyPhen possibly damaging (0.726); called by muse, mutect2, varscan2
- MAP3K5 | c.464A>T p.E155V | Missense Mutation (SNP) | VAF 20/84 reads (24%) | SIFT deleterious (0); PolyPhen probably damaging (0.991); called by muse, mutect2, varscan2
- MECOM | c.2027A>T p.D676V (on ENST00000468789 / NM_001105078.4; = p.D864V on NM_004991.4) | Missense Mutation (SNP) | VAF 12/61 reads (20%) | SIFT tolerated (0.1); PolyPhen probably damaging (0.994); called by muse, mutect2, varscan2
- NAP1L4 | c.847C>G p.Q283E | Missense Mutation (SNP) | VAF 17/78 reads (22%) | SIFT tolerated (0.38); PolyPhen benign (0.01); called by muse, mutect2, varscan2
- NECAB1 | c.884A>T p.N295I | Missense Mutation (SNP) | VAF 9/123 reads (7%) | SIFT deleterious (0); PolyPhen possibly damaging (0.596); called by muse, mutect2
- NOTCH1 | c.4054del p.C1352Afs*93 | Frame Shift Del (DEL) | VAF 6/12 reads (50%) | called by mutect2, varscan2
- NPHP3 | c.1385C>G p.T462S | Missense Mutation (SNP) | VAF 29/69 reads (42%) | SIFT tolerated (0.84); PolyPhen benign (0); called by muse, mutect2, varscan2
- NR2F2 | c.850C>T p.R284W | Missense Mutation (SNP) | VAF 5/47 reads (11%) | SIFT deleterious (0); PolyPhen probably damaging (0.997); called by muse, mutect2, varscan2
- PFDN2 | c.382G>A p.G128R | Missense Mutation (SNP) | VAF 8/154 reads (5%) | SIFT deleterious (0); PolyPhen probably damaging (0.995); called by muse, mutect2
- PHKA1 | c.3311del p.E1104Gfs*12 | Frame Shift Del (DEL) | VAF 12/18 reads (67%) | called by mutect2, varscan2
- RASGRF1 | c.1700C>A p.S567* | Nonsense Mutation (SNP) | VAF 30/72 reads (42%) | called by muse, mutect2, varscan2
- SLC47A1 | c.1561A>T p.M521L | Missense Mutation (SNP) | VAF 20/39 reads (51%) | SIFT tolerated (0.76); PolyPhen benign (0); called by muse, mutect2, varscan2
- SLC6A1 | c.680T>C p.F227S | Missense Mutation (SNP) | VAF 10/46 reads (22%) | SIFT deleterious (0); PolyPhen probably damaging (0.958); called by muse, mutect2, varscan2
- SOCS5 | c.1299G>T p.W433C | Missense Mutation (SNP) | VAF 17/58 reads (29%) | SIFT deleterious (0); PolyPhen probably damaging (0.995); called by muse, mutect2, varscan2
- SVIL | c.494C>T p.S165F | Missense Mutation (SNP) | VAF 7/53 reads (13%) | SIFT deleterious (0.03); PolyPhen benign (0.29); called by muse, mutect2, varscan2
- TACC2 | c.6480G>C p.E2160D (on ENST00000334433; = p.E238D on NM_006997.4) | Missense Mutation (SNP) | VAF 27/73 reads (37%) | SIFT deleterious (0.02); PolyPhen benign (0.263); called by muse, mutect2, varscan2
- TAS2R13 | c.331A>G p.I111V | Missense Mutation (SNP) | VAF 61/106 reads (58%) | SIFT deleterious (0); PolyPhen probably damaging (0.979); called by muse, mutect2, varscan2
- TMEM254 | c.234dup p.A79Cfs*8 | Frame Shift Ins (INS) | VAF 13/80 reads (16%) | called by mutect2, pindel, varscan2
- TRAV17 | c.116C>A p.A39D | Missense Mutation (SNP) | VAF 8/31 reads (26%) | SIFT tolerated (0.09); PolyPhen probably damaging (0.943); called by muse, mutect2, varscan2
- TRPM3 | c.4473C>G p.D1491E (on ENST00000357533 / NM_001366142.2; = p.D1346E on NM_020952.6) | Missense Mutation (SNP) | VAF 10/18 reads (56%) | SIFT tolerated, low confidence (0.05); PolyPhen benign (0.005); called by muse, mutect2, varscan2
- YEATS2 | c.385A>G p.R129G | Missense Mutation (SNP) | VAF 42/88 reads (48%) | SIFT tolerated (0.65); PolyPhen benign (0); called by muse, mutect2, varscan2
- ZC3H8 | c.79G>T p.D27Y | Missense Mutation (SNP) | VAF 10/89 reads (11%) | SIFT deleterious, low confidence (0); PolyPhen benign (0.061); called by muse, mutect2, varscan2
- ZNF107 | c.1403A>T p.Y468F | Missense Mutation (SNP) | VAF 19/38 reads (50%) | SIFT tolerated (0.1); PolyPhen possibly damaging (0.528); called by muse, mutect2, varscan2
- ASAP1 | c.2319G>A p.Q773= | Silent (SNP) | VAF 37/248 reads (15%) | catalogued as rs149904556; called by muse, mutect2, varscan2
- C6 | c.1638C>G p.G546= | Silent (SNP) | VAF 12/89 reads (13%) | catalogued as COSV99666873; called by muse, mutect2, varscan2
- CHST3 | c.1320G>A p.V440= | Silent (SNP) | VAF 4/46 reads (9%) | catalogued as rs1330683706; called by muse, mutect2
- CLCN2 | c.633C>T p.I211= | Silent (SNP) | VAF 18/71 reads (25%) | catalogued as rs370199115; called by muse, mutect2, varscan2
- INTS8 | c.621A>G p.K207= | Silent (SNP) | VAF 37/104 reads (36%) | called by muse, mutect2, varscan2
- KCNJ2 | c.285A>G p.S95= | Silent (SNP) | VAF 85/232 reads (37%) | called by muse, mutect2, varscan2
- KRTAP1-1 | c.402C>T p.C134= | Silent (SNP) | VAF 4/70 reads (6%) | catalogued as rs570985299, COSV60398580; called by muse, mutect2
- NOTCH3 | c.336C>T p.F112= | Silent (SNP) | VAF 86/147 reads (59%) | called by muse, mutect2, varscan2
- NWD1 | c.4122C>T p.Y1374= | Silent (SNP) | VAF 7/45 reads (16%) | catalogued as rs781251160, COSV60341567; called by muse, mutect2, varscan2
- NYNRIN | c.2442C>T p.C814= | Silent (SNP) | VAF 5/36 reads (14%) | called by muse, mutect2, varscan2
- OR2T12 | c.894C>A p.A298= | Silent (SNP) | VAF 19/113 reads (17%) | called by muse, mutect2
- PFDN5 | c.186A>G p.L62= | Silent (SNP) | VAF 23/50 reads (46%) | catalogued as rs769147478; called by muse, mutect2, varscan2
- RBP3 | c.1839C>T p.P613= | Silent (SNP) | VAF 8/44 reads (18%) | catalogued as rs782278294; called by muse, mutect2, varscan2
- RHCE | c.543G>A p.L181= | Silent (SNP) | VAF 65/185 reads (35%) | called by muse, mutect2, varscan2
- RYR3 | c.6645C>T p.S2215= | Silent (SNP) | VAF 12/49 reads (24%) | catalogued as rs772207338, COSV100774415; called by muse, mutect2, varscan2
- SELENOV | c.189T>C p.T63= | Silent (SNP) | VAF 7/41 reads (17%) | called by muse, mutect2, varscan2
- SHMT2 | c.945C>A p.I315= | Silent (SNP) | VAF 17/85 reads (20%) | called by muse, mutect2, varscan2
- SLC25A36 | c.663A>G p.K221= | Silent (SNP) | VAF 15/50 reads (30%) | called by muse, mutect2, varscan2
- SLC30A5 | c.108A>G p.L36= | Silent (SNP) | VAF 16/27 reads (59%) | catalogued as rs1456876924; called by muse, mutect2, varscan2
- TAPBPL | c.726C>T p.T242= | Silent (SNP) | VAF 23/108 reads (21%) | catalogued as rs758207098; called by muse, mutect2, varscan2
- ALKBH3 | c.460-4177G>A | Intron (SNP) | VAF 15/36 reads (42%) | called by muse, mutect2, varscan2
- MIR1302-3 | n.68T>A | RNA (SNP) | VAF 58/500 reads (12%) | called by muse, varscan2
- MIR523 | n.52A>C | RNA (SNP) | VAF 14/92 reads (15%) | called by muse, varscan2
